Somatic mutation profile of tumor specimen TCGA-V1-A8WV-01A (aliquot TCGA-V1-A8WV-01A-11D-A377-08) from TCGA case TCGA-V1-A8WV, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8WV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bbb5271-ec9b-4501-b79a-c9168833c7f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A8WV-10A (Blood Derived Normal), aliquot TCGA-V1-A8WV-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27df1e0a-33b3-4f23-a6b6-4edf162abee8

The open-access MAF lists 45 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Frame Shift Del 4, Splice Site 2, 5'Flank 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG1 | c.287T>A p.V96E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100112041; called by muse, mutect2, varscan2
- AMD1 | c.209T>G p.M70R | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100924520; called by muse, mutect2, varscan2
- CACNA1E | c.2635C>T p.R879W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs771126920, CM162248, COSV62447844; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH26 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs566034047, COSV54848857; called by muse, mutect2, varscan2
- CENPE | c.7143+1G>A p.X2381_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99478847; called by muse, mutect2, varscan2
- CSMD3 | c.9937G>T p.V3313F (on ENST00000297405 / NM_001363185.1; = p.V3144F on NM_052900.3) | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs774163140, COSV52267054; called by muse, mutect2, varscan2
- DOCK7 | c.2134T>A p.W712R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225649; called by muse, mutect2, varscan2
- DONSON | c.1483T>C p.S495P | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV99279487; called by muse, mutect2, varscan2
- DSEL | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100025992, COSV100026276; called by muse, mutect2
- ERBIN | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420812774, COSV99397639; called by muse, mutect2, varscan2
- HCRTR2 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100904554; called by muse, mutect2, varscan2
- IGLV1-47 | c.271G>C p.A91P | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs751187395; called by muse, mutect2, varscan2
- MACF1 | c.14873A>G p.E4958G (on ENST00000372915; = p.E2891G on NM_012090.5) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99246290; called by muse, mutect2, varscan2
- MAGEA12 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 71/111 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs1556833500, COSV100757013, COSV63295146; called by muse, mutect2, varscan2
- MAGI2 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV100836084; called by muse, mutect2, varscan2
- MMP26 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs1487880930, COSV100332233; called by muse, mutect2, varscan2
- MMP9 | c.2111G>T p.C704F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100812447; called by muse, mutect2, varscan2
- NCOA5 | c.737G>A p.S246N | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99275929; called by muse, mutect2, varscan2
- NEBL | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs752438492, COSV101008953; called by muse, mutect2, varscan2
- PCDHGA3 | c.18T>A p.S6R | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99544956; called by muse, mutect2, varscan2
- PCM1 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100279442; called by muse, mutect2, varscan2
- PLXNA3 | c.3745G>A p.A1249T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100860195; called by muse, mutect2, varscan2
- POM121L12 | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101374966, COSV68694803; called by muse, mutect2, varscan2
- SALL1 | c.1619G>A p.S540N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV99179721; called by muse, mutect2, varscan2
- SEMA6C | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs370815350; called by muse, mutect2, varscan2
- SHPRH | c.3985G>A p.E1329K (on ENST00000275233 / NM_001042683.3; = p.E1333K on NM_173082.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV51607969; called by muse, mutect2
- SLC26A2 | c.694del p.Y232Ifs*3 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs774842972; called by mutect2, pindel, varscan2
- TMEM198 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs369931895, COSV99525431; called by muse, mutect2, varscan2
- VGLL3 | c.652T>C p.S218P | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1438894720, COSV101052044; called by muse, mutect2, varscan2
- ZNF816 | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99554681; called by muse, mutect2, varscan2
- ACTR6 | c.1149_1155del p.E384Dfs*16 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- CCT2 | c.246dup p.V83Sfs*4 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | called by mutect2, pindel
- KLF5 | c.1151_1167del p.Y384Ffs*11 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- MBD1 | c.103dup p.Y35Lfs*14 | Frame Shift Ins (INS) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- SPATA20 | c.1378_1393del p.R460* (on ENST00000356488 / NM_001258372.1; = p.R476* on NM_022827.4) | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- TUT4 | c.1636-12_1644del p.X546_splice | Splice Site (DEL) | VAF 10/54 reads (19%) | called by pindel, varscan2
- DSCC1 | c.258A>G p.A86= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs1436841111, COSV100558400; called by muse, mutect2, varscan2
- GPR107 | c.702A>C p.P234= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100714741; called by muse, mutect2, varscan2
- IL17REL | c.558G>A p.A186= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs148168797, COSV100377428; called by muse, mutect2, varscan2
- PHLDB1 | c.2913C>T p.S971= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100616731; called by muse, varscan2
- PRMT3 | c.738C>T p.F246= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV58175580; called by muse, mutect2, varscan2
- TCIRG1 | c.2283C>T p.G761= | Silent (SNP) | VAF 21/165 reads (13%) | catalogued as COSV99693568; called by muse, mutect2, varscan2
- TMTC3 | c.834A>G p.T278= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV99898611; called by muse, mutect2
- AP000769.3 | chr11:65503945 T>G | 5'Flank (SNP) | VAF 5/17 reads (29%) | catalogued as rs1252316325; called by muse, mutect2, varscan2
- FUT7 | chr9:137034692 C>A | 5'Flank (SNP) | VAF 24/94 reads (26%) | catalogued as rs535490102; called by muse, mutect2, varscan2
